Somatic mutation profile of tumor specimen HTMCP-03-06-02118-01A (aliquot HTMCP-03-06-02118-01A-01D-5099) from CGCI case HTMCP-03-06-02118, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2.
Specimen HTMCP-03-06-02118-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d081e66-e7a0-47b4-ac92-d40c13e4edb6.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02118-10A (Blood Derived Normal), aliquot HTMCP-03-06-02118-10A-01D-5099; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/901592c1-e46a-4c70-a97f-6737e973e925

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Frame Shift Ins 1, 3'UTR 1, In Frame Del 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 47/108 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRG4 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 97/154 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as rs138853777; called by muse, mutect2, varscan2
- AUTS2 | c.3539C>T p.P1180L | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100716050; called by muse, mutect2, varscan2
- COL11A2 | c.2326C>T p.R776C (on ENST00000341947 / NM_080680.3; = p.R669C on NM_080679.2) | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs776701792, COSV59493332; called by muse, mutect2, varscan2
- COL7A1 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as rs761630796; called by muse, varscan2
- ITIH2 | c.1281C>T p.G427= | Splice Region (SNP) | VAF 26/91 reads (29%) | catalogued as rs769442335, COSV100623249, COSV100623445; called by muse, mutect2, varscan2
- NYAP1 | c.2006G>A p.R669H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs372063908; called by muse, varscan2
- PCDHGA12 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 71/102 reads (70%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.052); catalogued as rs767521224, COSV52741799; called by muse, mutect2, varscan2
- PLIN4 | c.1408G>A p.V470I (on ENST00000301286; = p.V485I on NM_001367868.2) | Missense Mutation (SNP) | VAF 64/227 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.226); catalogued as rs759827975; called by muse, mutect2, varscan2
- PPIP5K2 | c.3337C>T p.R1113* | Nonsense Mutation (SNP) | VAF 77/134 reads (57%) | catalogued as rs1554225502; called by muse, mutect2, varscan2
- PRRC2B | c.6547G>A p.V2183M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.439); catalogued as rs755958302, COSV57645566; called by mutect2, varscan2
- SCN9A | c.4138G>A p.V1380M (on ENST00000303354; = p.V1369M on NM_002977.3) | Missense Mutation (SNP) | VAF 110/173 reads (64%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.966); catalogued as COSV57602719; called by muse, mutect2, varscan2
- WDPCP | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs374189367; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF546 | c.1821A>T p.K607N | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100713502, COSV61257872; called by muse, mutect2, varscan2
- CASZ1 | c.232dup p.R78Pfs*55 | Frame Shift Ins (INS) | VAF 41/70 reads (59%) | called by mutect2, pindel, varscan2
- ERVW-1 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- RARG | c.1178G>A p.G393E | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TFG | c.805_807del p.G269del | In Frame Del (DEL) | VAF 21/149 reads (14%) | called by mutect2, pindel, varscan2
- TMTC1 | c.1612C>G p.Q538E (on ENST00000539277 / NM_001193451.2; = p.Q430E on NM_175861.3) | Missense Mutation (SNP) | VAF 70/255 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- VPS8 | c.696A>T p.K232N (on ENST00000625842 / NM_001349294.1; = p.K230N on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.65); called by muse, mutect2
- ZMYM1 | c.2779G>A p.G927S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANO8 | c.2295C>T p.F765= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as rs757985412; called by muse, mutect2, varscan2
- MYEF2 | c.1752C>T p.G584= | Silent (SNP) | VAF 35/160 reads (22%) | called by muse, mutect2, varscan2
- PLEKHH1 | c.78C>T p.F26= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs750039536; called by muse, mutect2, varscan2
- SALL1 | c.1872C>T p.S624= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs143548629; called by muse, varscan2
- STAB2 | c.4860C>T p.F1620= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as rs944580385, COSV66335802; called by muse, mutect2, varscan2
- ATP2B2 | c.*236G>A | 3'UTR (SNP) | VAF 22/69 reads (32%) | catalogued as rs201411918; called by muse, mutect2, varscan2
